Somatic mutation profile of tumor specimen ALCH-B2UE-TTP1-A (aliquot ALCH-B2UE-TTP1-A-1-0-D-A78Q-36) from ALCHEMIST case ALCH-B2UE, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 82.2 years (30,030 days).
Specimen ALCH-B2UE-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e59ab3ff-f97d-4453-95bf-df811f8f04fe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2UE-NB1-A (Blood Derived Normal), aliquot ALCH-B2UE-NB1-A-1-0-D-A78Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ddf1674f-b9ec-4d52-ba8e-a4869b8182e3

The open-access MAF lists 158 somatic variants for this specimen: 102 protein-altering or splice-affecting, 35 silent, 21 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 90, Silent 35, Intron 14, Nonsense Mutation 4, Splice Site 3, RNA 3, 3'UTR 2, 5'Flank 2, Frame Shift Del 2, Frame Shift Ins 1, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 36/178 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- ADA2 | c.220G>T p.A74S | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.602); catalogued as rs1250629456; called by muse, mutect2
- AHCTF1 | c.5350G>A p.V1784M (on ENST00000366508; = p.V1758M on NM_015446.5) | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs776106976; called by muse, mutect2, varscan2
- ASCL1 | c.292C>T p.R98C | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1334370186, COSV57151894; called by muse, mutect2, varscan2
- COL5A2 | c.3310-1G>T p.X1104_splice | Splice Site (SNP) | VAF 18/161 reads (11%) | catalogued as COSV100880001; called by muse, mutect2
- DDX28 | c.150G>T p.Q50H | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.359); catalogued as rs1308823692; called by mutect2, varscan2
- GUCY2F | c.1133T>A p.L378Q | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs748101818, COSV54299835; called by muse, mutect2, varscan2
- HCN4 | c.1033G>T p.D345Y | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56087567, COSV99984033; called by muse, mutect2
- KATNB1 | c.633-8C>T | Splice Region (SNP) | VAF 13/64 reads (20%) | catalogued as rs1555583664; called by muse, mutect2, varscan2
- KCNH4 | c.634G>C p.V212L | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.014); catalogued as COSV52917377; called by muse, mutect2, varscan2
- KCNT2 | c.156C>G p.F52L | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.071); catalogued as COSV54089984; called by muse, mutect2
- MAGEB18 | c.143G>T p.R48I | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as COSV57465009; called by muse, mutect2, varscan2
- MGAM2 | c.4447G>A p.A1483T | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs1191628953; called by muse, mutect2, varscan2
- NPHS1 | c.1721C>A p.P574Q | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs966885472; called by muse, mutect2, varscan2
- NTRK3 | c.1996G>T p.G666C | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62301349; called by muse, mutect2
- OPN3 | c.693+1G>A p.X231_splice | Splice Site (SNP) | VAF 7/19 reads (37%) | catalogued as rs1250980416; called by muse, varscan2
- OPRPN | c.278T>A p.I93N | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.557); catalogued as rs566298040, COSV68193383; called by muse, mutect2
- OR11L1 | c.795C>A p.H265Q | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0.014); catalogued as COSV63313492; called by muse, mutect2, varscan2
- OR4K17 | c.315C>G p.H105Q | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV100210498; called by muse, mutect2, varscan2
- PARD6G | c.1069C>T p.R357C | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.791); catalogued as rs758328356, COSV100783399; called by muse, mutect2, varscan2
- PCARE | c.2823G>A p.W941* | Nonsense Mutation (SNP) | VAF 7/40 reads (18%) | catalogued as COSV59056301; called by muse, mutect2
- PCDHB14 | c.656C>A p.S219Y | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as rs781926933, COSV53390206; called by muse, mutect2, varscan2
- PDZD7 | c.2467C>T p.P823S | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.935); catalogued as COSV100932142; called by muse, mutect2, varscan2
- PNKP | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 25/196 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.055); catalogued as rs1412623964; called by muse, mutect2, varscan2
- RYR2 | c.413C>A p.S138Y | Missense Mutation (SNP) | VAF 38/158 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV63704388; called by muse, mutect2, varscan2
- SLC27A6 | c.927G>C p.Q309H | Missense Mutation (SNP) | VAF 21/178 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as rs1327188263; called by muse, mutect2, varscan2
- SLC44A5 | c.1431C>G p.C477W | Missense Mutation (SNP) | VAF 15/157 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63775591; called by muse, mutect2
- SLITRK1 | c.1811C>A p.T604K | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0.057); catalogued as rs766912287; called by muse, mutect2, varscan2
- SRCAP | c.9362G>T p.R3121L | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV52667413; called by muse, mutect2, varscan2
- TMC2 | c.2638G>A p.G880R | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs199831022, COSV100727656, COSV62649835; called by muse, mutect2, varscan2
- TMEM106B | c.539G>A p.R180H | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.761); catalogued as rs746430474, COSV67544781; called by muse, mutect2, varscan2
- XIRP2 | c.3328G>T p.D1110Y (on ENST00000628543; = p.D1285Y on NM_152381.6) | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1257559225; called by muse, varscan2
- ZNF648 | c.1477C>T p.R493W | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.69); catalogued as rs562606540, COSV60570071; called by muse, mutect2, varscan2
- ADA2 | c.219G>T p.E73D | Missense Mutation (SNP) | VAF 11/146 reads (8%) | SIFT tolerated (0.48); PolyPhen benign (0.031); called by muse, mutect2
- ADAMTS12 | c.239G>T p.R80M | Missense Mutation (SNP) | VAF 70/290 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- ADGRA3 | c.2717C>T p.A906V | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.654); called by mutect2, varscan2
- AGK | c.1145C>G p.S382C | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- AGTPBP1 | c.3342G>T p.K1114N (on ENST00000357081 / NM_001330701.2; = p.K1074N on NM_015239.2) | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- ARL14EPL | c.72C>A p.N24K | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT tolerated (0.84); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ASPSCR1 | c.1258G>T p.V420L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- C2orf16 | c.3726A>C p.L1242F | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- CADM3 | c.1082C>G p.T361S (on ENST00000368125 / NM_001127173.3; = p.T395S on NM_021189.5) | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CAMSAP3 | c.1738G>A p.E580K | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (0.66); PolyPhen benign (0.346); called by muse, mutect2
- CCDC172 | c.127G>C p.E43Q | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- CD53 | c.287A>G p.E96G | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CLRN2 | c.575G>A p.C192Y | Missense Mutation (SNP) | VAF 20/254 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); called by muse, mutect2
- CMIP | c.403C>T p.P135S (on ENST00000537098 / NM_198390.2; = p.P41S on NM_030629.3) | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CNTNAP4 | c.3558C>G p.S1186R | Missense Mutation (SNP) | VAF 19/140 reads (14%) | SIFT tolerated (0.64); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- COL27A1 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CRISP1 | c.77C>A p.A26D | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- EBLN1 | c.714C>A p.Y238* | Nonsense Mutation (SNP) | VAF 12/48 reads (25%) | called by muse, mutect2, varscan2
- EEF1A1 | c.424A>G p.T142A | Missense Mutation (SNP) | VAF 8/131 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.663); called by muse, mutect2
- FAT1 | c.4544A>T p.Y1515F | Missense Mutation (SNP) | VAF 45/174 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- FAT4 | c.5399G>A p.R1800K | Missense Mutation (SNP) | VAF 22/167 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FCRL2 | c.829G>C p.A277P | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- FEZ1 | c.390T>G p.N130K | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.949); called by muse, mutect2
- GK3P | c.73T>A p.F25I | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- GPS2 | c.282A>T p.L94F | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- HDAC9 | c.2567C>T p.A856V | Missense Mutation (SNP) | VAF 15/159 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); called by muse, mutect2
- IL31RA | c.8T>A p.I3N | Missense Mutation (SNP) | VAF 28/428 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.663); called by muse, mutect2
- ITPRID2 | c.1093_1099del p.G365Qfs*47 | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | called by mutect2, pindel
- KIF1A | c.1856G>A p.W619* | Nonsense Mutation (SNP) | VAF 9/57 reads (16%) | called by muse, mutect2, varscan2
- KLHL33 | c.956C>T p.A319V | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated (0.66); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LAMA3 | c.7699C>G p.L2567V (on ENST00000313654 / NM_198129.4; = p.L958V on NM_000227.6) | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LAPTM4B | c.892T>A p.Y298N (on ENST00000445593; = p.Y207N on NM_018407.6) | Missense Mutation (SNP) | VAF 12/202 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- MAPKAP1 | c.817C>A p.L273M | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- MXRA5 | c.2686G>A p.E896K | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYH3 | c.2791G>T p.E931* | Nonsense Mutation (SNP) | VAF 36/269 reads (13%) | called by muse, mutect2, varscan2
- NPR2 | c.2458A>T p.T820S | Missense Mutation (SNP) | VAF 61/211 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR5AS1 | c.815_817delinsTT p.K272Ifs*17 | Frame Shift Del (DEL) | VAF 10/48 reads (21%) | called by pindel, varscan2*
- OSMR | c.574G>T p.D192Y | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PCDH1 | c.251C>T p.P84L | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); called by muse, mutect2
- PDE6C | c.1016C>T p.A339V | Missense Mutation (SNP) | VAF 25/263 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.243); called by muse, mutect2
- PKP4 | c.3349A>G p.S1117G | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PLEKHA6 | c.1161G>T p.W387C | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, varscan2
- POTEE | c.941G>T p.C314F | Missense Mutation (SNP) | VAF 24/352 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.259); called by muse, mutect2
- PTBP1 | c.1310G>A p.R437H (on ENST00000349038 / NM_031991.4; = p.R463H on NM_002819.5) | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- RBM23 | c.722C>T p.S241L (on ENST00000359890 / NM_001077351.2; = p.S225L on NM_018107.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- RUFY4 | c.1548G>T p.M516I | Missense Mutation (SNP) | VAF 11/134 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.01); called by muse, mutect2
- SLC5A1 | c.1130-1G>A p.X377_splice | Splice Site (SNP) | VAF 22/193 reads (11%) | called by muse, mutect2, varscan2
- SLC5A1 | c.1717C>A p.L573M | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.896); called by muse, mutect2
- SMOC2 | c.1125C>A p.F375L (on ENST00000356284 / NM_001166412.2; = p.F386L on NM_022138.3) | Missense Mutation (SNP) | VAF 23/252 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.401); called by muse, mutect2
- SPATA31A1 | c.3317C>A p.P1106H | Missense Mutation (SNP) | VAF 50/293 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- SPO11 | c.510A>G p.I170M | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- SYT6 | c.410C>A p.T137K (on ENST00000610222 / NM_001366225.1; = p.T52K on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- TENM3 | c.7428_7429insA p.R2477Tfs*260 | Frame Shift Ins (INS) | VAF 20/86 reads (23%) | called by mutect2, pindel*, varscan2
- TGFBRAP1 | c.1898A>T p.E633V | Missense Mutation (SNP) | VAF 28/247 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- TGM6 | c.590G>T p.S197I | Missense Mutation (SNP) | VAF 18/220 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); called by muse, mutect2
- THADA | c.3455C>T p.S1152L | Missense Mutation (SNP) | VAF 9/129 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- THRB | c.1153G>C p.G385R | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2
- TMTC1 | c.554G>T p.R185M (on ENST00000539277 / NM_001193451.2; = p.R77M on NM_175861.3) | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- TNPO3 | c.1049G>T p.G350V | Missense Mutation (SNP) | VAF 6/95 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.316); called by muse, mutect2
- TRPM6 | c.4283G>T p.S1428I | Missense Mutation (SNP) | VAF 35/318 reads (11%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- TSHR | c.971A>T p.Q324L | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- UNC93B1 | c.1538G>A p.R513Q | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2
- WDR35 | c.599A>T p.N200I | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- WDR49 | c.375C>G p.I125M (on ENST00000308378 / NM_001366158.1; = p.I466M on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/185 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.177); called by muse, mutect2
- YWHAE | c.224_226del p.G75del | In Frame Del (DEL) | VAF 18/166 reads (11%) | called by pindel, varscan2
- ZFP41 | c.529G>T p.G177W | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF556 | c.623G>T p.C208F | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF669 | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF726 | c.1003C>A p.H335N | Missense Mutation (SNP) | VAF 30/176 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AKNAD1 | c.1722C>A p.A574= | Silent (SNP) | VAF 18/131 reads (14%) | catalogued as rs990248299; called by muse, mutect2, varscan2
- ALK | c.1665C>A p.L555= | Silent (SNP) | VAF 37/165 reads (22%) | called by muse, mutect2, varscan2
- ARHGEF10L | c.2436G>T p.L812= | Silent (SNP) | VAF 18/188 reads (10%) | called by muse, mutect2, varscan2
- C10orf53 | c.33T>C p.Y11= | Silent (SNP) | VAF 23/130 reads (18%) | called by muse, mutect2, varscan2
- CAPNS2 | c.252A>G p.Q84= | Silent (SNP) | VAF 11/107 reads (10%) | catalogued as rs369578789; called by muse, mutect2, varscan2
- CD101 | c.198G>T p.P66= | Silent (SNP) | VAF 13/74 reads (18%) | catalogued as COSV99869420; called by muse, mutect2, varscan2
- CDC14C | c.1203G>T p.L401= (on ENST00000428251; = p.L294= on NM_152627.3) | Silent (SNP) | VAF 13/116 reads (11%) | called by muse, varscan2
- CDH4 | c.1566C>T p.P522= | Silent (SNP) | VAF 9/117 reads (8%) | catalogued as rs753718602, COSV100849739; called by muse, mutect2
- CPLX2 | c.276G>T p.G92= | Silent (SNP) | VAF 7/56 reads (13%) | called by muse, varscan2
- ERVW-1 | c.1317C>A p.G439= | Silent (SNP) | VAF 12/162 reads (7%) | catalogued as rs908135205; called by muse, mutect2
- ESCO1 | c.2328C>T p.S776= | Silent (SNP) | VAF 8/72 reads (11%) | called by muse, mutect2, varscan2
- FAM135B | c.3694C>A p.R1232= | Silent (SNP) | VAF 16/195 reads (8%) | catalogued as COSV52706786; called by muse, mutect2
- IFT80 | c.174C>T p.Y58= | Silent (SNP) | VAF 8/92 reads (9%) | catalogued as rs1156889261, COSV58448233; called by muse, mutect2
- JAG2 | c.249G>T p.T83= | Silent (SNP) | VAF 10/61 reads (16%) | called by muse, mutect2, varscan2
- KCNH7 | c.546G>T p.V182= | Silent (SNP) | VAF 16/154 reads (10%) | catalogued as rs1240397358; called by muse, mutect2
- KRT34 | c.75C>A p.A25= | Silent (SNP) | VAF 8/54 reads (15%) | called by muse, mutect2, varscan2
- LRRC45 | c.1326T>A p.R442= | Silent (SNP) | VAF 9/72 reads (13%) | called by muse, mutect2, varscan2
- MAPK13 | c.264G>T p.L88= | Silent (SNP) | VAF 9/112 reads (8%) | catalogued as COSV52983886; called by muse, mutect2
- MS4A2 | c.441C>A p.I147= | Silent (SNP) | VAF 22/218 reads (10%) | catalogued as COSV54013839; called by muse, mutect2, varscan2
- MYH6 | c.2976T>C p.A992= | Silent (SNP) | VAF 15/116 reads (13%) | called by muse, mutect2, varscan2
- NLRP3 | c.778C>A p.R260= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as COSV60220144; called by muse, mutect2, varscan2
- NOP16 | c.339G>T p.R113= | Silent (SNP) | VAF 23/135 reads (17%) | called by muse, mutect2, varscan2
- NOX4 | c.12C>A p.S4= | Silent (SNP) | VAF 6/84 reads (7%) | catalogued as COSV54467281; called by muse, mutect2
- OR13G1 | c.612C>A p.A204= | Silent (SNP) | VAF 17/206 reads (8%) | called by muse, mutect2
- OR2G3 | c.615G>T p.L205= | Silent (SNP) | VAF 23/124 reads (19%) | called by muse, mutect2, varscan2
- PDGFRA | c.72G>A p.Q24= | Silent (SNP) | VAF 10/50 reads (20%) | called by muse, mutect2, varscan2
- PRSS12 | c.1365C>T p.C455= | Silent (SNP) | VAF 36/220 reads (16%) | called by muse, mutect2, varscan2
- PSG11 | c.504C>T p.T168= | Silent (SNP) | VAF 17/175 reads (10%) | catalogued as rs754135693; called by muse, mutect2, varscan2
- SEL1L2 | c.750T>A p.A250= | Silent (SNP) | VAF 5/47 reads (11%) | called by muse, mutect2
- SH3PXD2B | c.882C>T p.H294= | Silent (SNP) | VAF 24/122 reads (20%) | called by muse, mutect2
- SLC14A2 | c.2412C>T p.Y804= | Silent (SNP) | VAF 8/75 reads (11%) | catalogued as rs1376091552; called by muse, mutect2, varscan2
- TLR4 | c.84C>A p.P28= | Silent (SNP) | VAF 42/199 reads (21%) | called by muse, mutect2, varscan2
- TMEM131 | c.4188G>A p.K1396= | Silent (SNP) | VAF 16/140 reads (11%) | called by muse, mutect2, varscan2
- USHBP1 | c.1743G>C p.V581= | Silent (SNP) | VAF 8/68 reads (12%) | called by muse, mutect2, varscan2
- ZNF717 | c.1398C>G p.L466= | Silent (SNP) | VAF 10/77 reads (13%) | called by muse, mutect2, varscan2
- CD300LD | chr17:74592616 A>G | 5'Flank (SNP) | VAF 8/65 reads (12%) | called by muse, mutect2, varscan2
- COG6 | c.623+48A>C | Intron (SNP) | VAF 19/195 reads (10%) | catalogued as rs759422615; called by muse, mutect2
- DNAJC19 | c.*690A>G | 3'UTR (SNP) | VAF 5/51 reads (10%) | catalogued as rs1370714837, COSV104423365; called by muse, mutect2
- GPR68 | c.-130+2719A>G | Intron (SNP) | VAF 19/86 reads (22%) | called by muse, mutect2, varscan2
- KCNIP4 | c.62-421154T>A | Intron (SNP) | VAF 12/108 reads (11%) | catalogued as COSV66171795; called by muse, mutect2, varscan2
- LINC01567 | n.214C>T | RNA (SNP) | VAF 13/174 reads (7%) | catalogued as rs969417003; called by muse, mutect2
- LINC01588 | n.834G>A | RNA (SNP) | VAF 11/99 reads (11%) | catalogued as rs773698832; called by muse, mutect2, varscan2
- MAU2 | c.1155+11C>G | Intron (SNP) | VAF 24/103 reads (23%) | catalogued as rs60890167; called by muse, mutect2, varscan2
- MAX | c.295+573A>G | Intron (SNP) | VAF 32/164 reads (20%) | called by muse, varscan2
- MRE11 | c.20+21A>T | Intron (SNP) | VAF 44/226 reads (19%) | called by muse, varscan2
- OR10D1P | n.112A>T | RNA (SNP) | VAF 33/169 reads (20%) | called by muse, mutect2, varscan2
- PDPR | c.848-175A>T | Intron (SNP) | VAF 12/162 reads (7%) | catalogued as rs769811496; called by muse, mutect2
- RIMS2 | c.4064-21207C>T | Intron (SNP) | VAF 7/39 reads (18%) | catalogued as rs926984897; called by muse, mutect2, varscan2
- SDSL | c.-143-1405G>T | Intron (SNP) | VAF 36/133 reads (27%) | called by muse, mutect2, varscan2
- SERPINC1 | c.*2A>C | 3'UTR (SNP) | VAF 22/136 reads (16%) | called by muse, mutect2, varscan2
- SLAIN2 | c.1360+10836A>G | Intron (SNP) | VAF 9/224 reads (4%) | catalogued as rs1291461224; called by muse, mutect2
- TDP1 | c.1644+3628A>T | Intron (SNP) | VAF 15/103 reads (15%) | called by muse, mutect2, varscan2
- TMPRSS11F | c.1015+2146A>G | Intron (SNP) | VAF 32/124 reads (26%) | catalogued as rs774701505; called by muse, mutect2, varscan2
- TYROBP | c.95-48C>T | Intron (SNP) | VAF 10/50 reads (20%) | called by muse, mutect2, varscan2
- UCHL5 | chr1:193059871 C>A | 5'Flank (SNP) | VAF 31/170 reads (18%) | called by muse, mutect2, varscan2
- USH2A | c.5298+43C>A | Intron (SNP) | VAF 9/29 reads (31%) | called by muse, mutect2, varscan2
